Somatic mutation profile of cancer-model specimen HCM-BROD-0041-C64-85A (2D Modified Conditionally Reprogrammed Cells, passage 19; aliquot HCM-BROD-0041-C64-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0041-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 7.3 years (2,655 days).
Specimen HCM-BROD-0041-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 19.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 598c8053-23f8-4595-97c9-fc167674517f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0041-C64-10A (Blood Derived Normal), aliquot HCM-BROD-0041-C64-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92b07db0-8f4a-439a-8d3d-b62af7c850a0

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 319/482 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 56/135 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 220/222 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TNFRSF4 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 77/423 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV55422311; called by muse, mutect2, varscan2
- IGF2BP2 | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP3CA | c.959C>A p.A320E | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- STARD9 | c.5959C>T p.P1987S | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- XK | c.333A>T p.K111N | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ZFHX4 | c.8415G>A p.S2805= | Silent (SNP) | VAF 93/194 reads (48%) | catalogued as rs368980001; called by muse, mutect2, varscan2
- NECTIN2 | c.1043-3814G>T | Intron (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
